Somatic mutation profile of tumor specimen C3N-03003-01 (aliquot CPT0224960006) from CPTAC case C3N-03003, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.1 years (14,654 days).
Specimen C3N-03003-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0b552bf-3c0d-42e8-b938-d6224bf48a89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03003-31 (Blood Derived Normal), aliquot CPT0225800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6385a258-1dfb-440f-9fa7-3b20ac77dee8

The open-access MAF lists 82 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 20, Intron 3, Nonsense Mutation 3, 5'Flank 2, RNA 2, In Frame Del 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.3508G>A p.G1170S | Missense Mutation (SNP) | VAF 193/461 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912891, CM051418, COSV61533548; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 185/3843 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.81del p.Y27* | Frame Shift Del (DEL) | VAF 49/87 reads (56%) | hotspot (GDC flag); catalogued as CM128488, COSV64291164, COSV64310374; called by mutect2, pindel, varscan2
- ADRA2A | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 70/85 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146469074; called by muse, mutect2, varscan2
- ATXN7 | c.2001G>A p.M667I | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs746909336; called by muse, mutect2, varscan2
- BMP6 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 191/489 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.155); catalogued as rs201357308; called by muse, mutect2, varscan2
- CENPB | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.121); catalogued as COSV100713480, COSV60144384; called by muse, varscan2
- CNTN3 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs764619298, COSV55167035; called by muse, mutect2, varscan2
- CNTNAP3 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 58/794 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1368677445; called by muse, mutect2
- COL22A1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.788); catalogued as rs1359249026, COSV57323312; called by muse, mutect2, varscan2
- COL6A6 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777867254, COSV62025230; called by muse, mutect2, varscan2
- CYP2A13 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV57839856; called by muse, mutect2, varscan2
- DKK2 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 69/143 reads (48%) | catalogued as rs528677483, COSV53396515, COSV53396966, COSV53400713; called by muse, mutect2, varscan2
- DNAH2 | c.6932C>A p.T2311N | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101209621; called by muse, mutect2, varscan2
- DNAH6 | c.11689G>A p.V3897I | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750884351; called by muse, mutect2, varscan2
- FOXD2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.286); catalogued as rs1471075642; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 94/374 reads (25%) | SIFT tolerated (0.14); catalogued as rs1425998903; called by muse, mutect2, varscan2
- GPSM3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs964502715; called by muse, mutect2, varscan2
- HIBADH | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 90/312 reads (29%) | catalogued as rs1215114877; called by muse, mutect2, varscan2
- HPSE2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 110/139 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs778752620, COSV65189532; called by muse, mutect2, varscan2
- HRNR | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 329/705 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs537328568, COSV64260052; called by muse, mutect2, varscan2
- KDELR3 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs147788461; called by muse, mutect2, varscan2
- KRR1 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs375387200; called by muse, mutect2, varscan2
- KRTAP19-1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs199797669, COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- LCP1 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59943248; called by muse, mutect2, varscan2
- LDHAL6A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759714342; called by muse, mutect2, varscan2
- MFSD9 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 155/452 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs746332713; called by muse, mutect2, varscan2
- MUC16 | c.3983C>T p.T1328M | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1261277009, COSV67475867; called by muse, mutect2, varscan2
- PCDHB3 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV50631131; called by muse, mutect2, varscan2
- PRDM9 | c.606C>A p.Y202* | Nonsense Mutation (SNP) | VAF 132/305 reads (43%) | catalogued as rs754801668; called by muse, mutect2, varscan2
- QRSL1 | c.1058T>C p.I353T | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as rs754249822; called by muse, mutect2, varscan2
- RAB19 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 234/768 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1447472611, COSV52044000; called by muse, mutect2, varscan2
- RIMS3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs367654902; called by muse, mutect2, varscan2
- RP1 | c.5036C>T p.S1679L | Missense Mutation (SNP) | VAF 218/563 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1020552570, COSV55114017; called by muse, mutect2, varscan2
- SATB2 | c.2134A>G p.K712E | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146644021; called by muse, mutect2
- SRRT | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs559507893; called by muse, mutect2, varscan2
- TERT | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 290/670 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs749187042; called by muse, mutect2, varscan2
- TRPV5 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 170/599 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs145819800; called by muse, mutect2, varscan2
- TTN | c.77819A>G p.D25940G (on ENST00000591111; = p.D18516G on NM_003319.4) | Missense Mutation (SNP) | VAF 131/341 reads (38%) | PolyPhen benign (0.074); catalogued as rs926217231; called by muse, mutect2, varscan2
- UBXN8 | c.262_264del p.Q88del | In Frame Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs766824838; called by pindel, varscan2
- VSTM2A | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 567/1875 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs144355001; called by muse, mutect2, varscan2
- AP5B1 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDEM1 | c.507C>G p.D169E | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ENTPD2 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 175/440 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- HEATR5B | c.6036T>A p.H2012Q | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC2 | c.4539G>T p.L1513F | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LAP3 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRC8B | c.1574A>G p.Q525R | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LTBP3 | c.1194A>T p.K398N | Missense Mutation (SNP) | VAF 200/461 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MAGEL2 | c.2405A>G p.N802S | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NPHS1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 241/837 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- OR5T2 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TERT | c.2546T>C p.M849T | Missense Mutation (SNP) | VAF 139/327 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TNRC6A | c.4208A>T p.Q1403L | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- BPIFB3 | c.117C>T p.L39= | Silent (SNP) | VAF 101/230 reads (44%) | catalogued as rs763851993, COSV64957157; called by muse, mutect2, varscan2
- CEACAM21 | c.87C>T p.N29= | Silent (SNP) | VAF 183/675 reads (27%) | catalogued as rs545179785, COSV51815274; called by muse, mutect2, varscan2
- DDX43 | c.12C>T p.H4= | Silent (SNP) | VAF 89/196 reads (45%) | catalogued as rs768641284, COSV64837693; called by muse, mutect2, varscan2
- FBLN2 | c.2734C>T p.L912= | Silent (SNP) | VAF 22/341 reads (6%) | called by muse, mutect2
- IKZF1 | c.504C>T p.S168= | Silent (SNP) | VAF 79/388 reads (20%) | catalogued as rs573718333; called by muse, mutect2, varscan2
- KIAA1217 | c.2661G>T p.A887= | Silent (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- KRT25 | c.1008G>A p.A336= | Silent (SNP) | VAF 240/545 reads (44%) | catalogued as rs1459792230, COSV100379925, COSV56443491; called by muse, mutect2, varscan2
- ME1 | c.678C>T p.D226= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs186078215; called by muse, mutect2, varscan2
- MROH2B | c.2523T>C p.P841= | Silent (SNP) | VAF 111/239 reads (46%) | called by muse, mutect2, varscan2
- MVP | c.2277C>T p.L759= | Silent (SNP) | VAF 167/383 reads (44%) | called by muse, mutect2, varscan2
- MYO15A | c.1272G>A p.P424= | Silent (SNP) | VAF 81/171 reads (47%) | catalogued as rs372551257; called by muse, mutect2, varscan2
- NOVA2 | c.744C>T p.A248= | Silent (SNP) | VAF 77/211 reads (36%) | catalogued as rs1181356586; called by muse, mutect2, varscan2
- OR4C6 | c.297G>C p.L99= | Silent (SNP) | VAF 125/306 reads (41%) | catalogued as COSV58602826; called by muse, mutect2, varscan2
- OTUD6A | c.204C>T p.D68= | Silent (SNP) | VAF 184/214 reads (86%) | catalogued as COSV57973566; called by muse, mutect2, varscan2
- PCLO | c.1761C>A p.T587= | Silent (SNP) | VAF 117/463 reads (25%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.768G>A p.K256= | Silent (SNP) | VAF 235/730 reads (32%) | called by muse, mutect2, varscan2
- SEMA7A | c.732C>T p.F244= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs1308504048, COSV56092445; called by muse, mutect2, varscan2
- TMEM132D | c.1422G>A p.S474= | Silent (SNP) | VAF 101/236 reads (43%) | catalogued as rs750428688, COSV70615097; called by muse, mutect2, varscan2
- TMEM17 | c.507G>A p.L169= | Silent (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- XIRP2 | c.6591A>G p.P2197= (on ENST00000628543; = p.P2372= on NM_152381.6) | Silent (SNP) | VAF 77/156 reads (49%) | catalogued as rs771938110; called by muse, mutect2, varscan2
- COL5A1 | c.654+7598G>A | Intron (SNP) | VAF 160/374 reads (43%) | catalogued as rs768504046; called by muse, mutect2, varscan2
- FOXO6 | chr1:41361926 G>A | 5'Flank (SNP) | VAF 99/226 reads (44%) | called by muse, mutect2, varscan2
- KLHL10 | c.-43G>A | 5'UTR (SNP) | VAF 81/181 reads (45%) | catalogued as rs782596232; called by muse, mutect2, varscan2
- OR6W1P | n.348C>T | RNA (SNP) | VAF 86/312 reads (28%) | catalogued as rs764127577; called by muse, mutect2, varscan2
- RPSA | c.-34+265G>A | Intron (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- SAMM50 | c.649-28G>A | Intron (SNP) | VAF 28/73 reads (38%) | catalogued as rs376802043; called by muse, mutect2
- TCP10L3 | n.122G>A | RNA (SNP) | VAF 106/211 reads (50%) | catalogued as rs1200897799; called by muse, mutect2, varscan2
- TTLL10 | chr1:1169019 C>T | 5'Flank (SNP) | VAF 188/450 reads (42%) | catalogued as rs370099729; called by muse, mutect2, varscan2
